CCDI case PBBYNN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/84affdf6-3959-4308-95bd-305feb072624

Demographics
Sex at birth: female.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 9.4 years (3,424 days).

Biospecimens (3 samples)
- Samples 0DMCR6, 0DMCR7 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMCR8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
